Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A176, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A176-01A (Primary Tumor).

[page 1 of 6]
Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Surgical Pathology Site Code Endometrium 654.1

DIAGNOSIS:

A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade II (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (4.7 x 3.2 x 1.7 cm) located in the posterior and right lateral uterine wall. The tumor invades 0.3 cm into the myometrium (total myometrial thickness, 2.3 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. All surgical resection margins are negative for tumor. There is an intramural leiomyoma (0.4 cm in greatest dimension) in the myometrium. The bilateral ovaries and fallopian tubes are not involved. Endometriosis is present on the posterior uterine serosa and cul-de-sac. [AJCC pT1bNOMX]

B-E. Lymph nodes, right pelvic, excisions: Multiple (7 external iliac, 7 internal iliac, 6 common iliac, 12 obturator) right pelvic lymph nodes are negative for tumor.

F-I. Lymph nodes, left pelvic, excisions: Multiple (8 external iliac, 2 internal iliac, 3 common iliac, 12 obturator) left pelvic lymph nodes are negative for tumor.

J, M. Lymph nodes, right and left para-aortic above the inferior mesenteric artery, excisions: Multiple (11 right, 12 left) para-aortic lymph nodes above the inferior mesenteric artery are negative for tumor.

K, N. Lymph nodes, right and left para-aortic below the inferior

[page 2 of 6]
mesenteric artery, excisions: Multiple (5 right, 5 left) para-aortic lymph nodes below the inferior mesenteric artery are negative for tumor.

L, O. Gonadal vessels, left and right, excision: The left and right gonadal vessels are negative for tumor.

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s).

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, left and right tubes and ovaries" is a 160.0 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The posterior uterine serosa and cul de sac has focal adhesions suspicious for endometriosis. There is a 4.7 x 3.2 x 1.7 cm polypoid mass in the posterior and right lateral wall of the endometrial cavity with 2.3 cm myometrial thickness. There is a single intramural leiomyoma (0.4 cm in greatest dimension). There is a 2.7 x 1.8 x 1.2 cm right ovary with a smooth outer surface and a solid cut surface with a 10.8 x 0.7 cm right fallopian tube. There is a 3.3 x 1.4 x 1.0 cm left ovary with a smooth outer surface and a solid cut surface with a 9.7 x 0.7 cm left fallopian tube. Representative sections submitted. Grossed by

B. Received fresh labeled "right pelvic nodes, internal" is a 3.0 x

[page 3 of 6]
2.2 x 1.3 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

C. Received fresh labeled "right pelvic nodes, external"
is a 8.0 x
5.0 x 3.0 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

D. Received fresh labeled "right pelvic nodes, common" is
a 4.1 x
2.5 x 2.0 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

E. Received fresh labeled "right pelvic nodes, obturator"
is a 8.5
x 6.0 x 3.5 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

F. Received fresh labeled "left pelvic nodes, internal"
is a 3.0 x
2.0 x 0.8 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

G. Received fresh labeled "left pelvic nodes, external"
is a 7.5 x
5.0 x 3.2 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

H. Received fresh labeled "left pelvic nodes, common" is
a 4.0 x
3.0 x 1.5 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

I. Received fresh labeled "left pelvic nodes, obturator"
is a 10.0
x 4.3 x 2.0 cm aggregate of adipose and lymphatic tissue.
All
lymphatic tissue submitted.

[page 4 of 6]
J. Received fresh labeled "right para-aortic nodes above the IMA" is a 6.7 x 4.0 x 1.0 cm aggregate of adipose and lymphatic tissue.

All lymphatic tissue submitted.

K. Received fresh labeled "right para-aortic nodes below the IMA" is a 4.2 x 2.7 x 1.3 cm aggregate of adipose and lymphatic tissue.

All lymphatic tissue submitted.

L. Received fresh labeled "right gonadal vessels" is a 6.0 cm in length by 0.6 cm in diameter portion of unremarkable blood vessel.

A representative section is submitted.

M. Received fresh labeled "left para-aortic nodes above the IMA" is

a 7.5 x 5.0 x 1.2 cm aggregate of adipose and lymphatic tissue. All

lymphatic tissue submitted.

N. Received fresh labeled "left para-aortic nodes below the IMA" is

a 2.8 x 2.2 x 1.4 cm aggregate of adipose and lymphatic tissue. All

lymphatic tissue submitted.

O. Received fresh labeled "left gonadal vessels" is a 6.0 cm in

length by 0.4 cm in diameter portion of unremarkable tan tubular

tissue. A representative section is submitted. Grossed by

BLOCK SUMMARY:

Part A: Uterus, left and right tubes and ovaries

- 1 Endometrium-1
- 2 Endometrium-2
- 3 Endometrium-3
- 4 Endometrium-4
- 5 Endometrium-5
- 6 Endometrium-6
- 7 Lower uterine segment
- 8 Cervix

[page 5 of 6]
- 9 Posterior uterine serosa
- 10 Uterine cul de sac
- 11 Right tube
- 12 Right ovary
- 13 left tube
- 14 Left ovary

Part B: Right Pelvic Lymph Nodes internal

- 1 Rt internal LNs 2 (B1)
- 2 Rt internal LNs 2 (B2)
- 3 Rt internal LN 1 (B3)
- 4 Rt internal LNs 2 (B4)

Part C: Right Pelvic Lymph Nodes external

- 1 Rt external LNs 4 (C1)
- 2 Rt external LN 1 (C2)
- 3 Rt external LN 1 (C3)
- 4 Rt external LN 1 (C4)
- 5 Rt external LN 1 (C5)

Part D: Right Pelvic Lymph Nodes common

- 1 Rt common LNs 4 (D1)
- 2 Rt common LNs 2 (D2)
- 3 Rt common LN 1 (D3)

Part E: Right Pelvic Lymph Nodes obturator

- 1 Rt obturator LNs 5 (E1)
- 2 Rt obturator LNs 3 (E2)
- 3 Rt obturator LN 1 (E3)
- 4 Rt obturator LNs 4 (E4)

Part F: Left Pelvic Nodes, internal

- 1 Left internal LNs 2 (F1)

Part G: Left Pelvic Nodes, external

- 1 Left external LNs 2 (G1)
- 2 Left external LNs 2 (G2)
- 3 Left external LN 1 (G3)
- 4 Left external LNs 2 (G4)
- 5 Left external LN 1 (G5)

Part H: Left Pelvic Nodes, common

- 1 Left common lns 4 (H1)
- 2 Left common lns 3 (H2)

Part I: Left Pelvic Nodes, obturator

- 1 Lt obturator LNS 2 (I1)

[page 6 of 6]
- 2 Lt obturator LNS 2 (I2)
- 3 Lt obturator LNS 3 (I3)
- 4 Lt obturator LNS 2 (I4)
- 5 Lt obturator LN 1 (I5)
- 6 Lt obturator LN 1 (I6)
- 7 Lt obturator LN 1 (I7)
- 8 Lt obturator LN 1 (I8)
- 9 Lt obturator LN 1 (I9)
- 10 Lt obturator LNs 2 (I10)

Part J: Right Para-aortic Lymph Nodes above IMA

- 1 Rt above IMA LN 1 (J1)
- 2 Rt above IMA LNS 4 (J2)
- 3 Rt above IMA LNS 3 (J3)
- 4 Rt above IMA LNS 3 (J4)
- 5 Rt above IMA LNS 4 (J4)
- 6 Rt above IMA LN 1 (J6)

Part K: Right Para-aortic Lymph Nodes below IMA

- 1 Rt below IMA LNs 4 (K1)
- 2 Rt below IMA LN 1 (K2)

Part L: Right Gonadal vessels

- 1 Rt gonadal vessels

Part M: Left Para-aortic Lymph Nodes above IMA

- 1 Lt PA above IMA 4 (M1)
- 2 Lt PA above IMA 3 (m2)
- 3 Lt PA above IMA lns 4 (M3)
- 4 Lt PA above IMA lns 1 (M4)

Part N: Left Para-aortic Lymph Nodes below IMA

- 1 Lt PA below IMA 1of2 (N1)
- 2 Lt PA below IMA 2of2 (N1)
- 3 Lt PA below IMA 1 (N2)
- 4 Lt PA below IMA 3 (N3)

Part O: Left Gonadal vessels

- 1 Lt gonadal vessels

Source: NCI Genomic Data Commons file bbfe1a43-368f-432b-a85e-002bcd7eed3a (TCGA-D1-A176.6F361A45-F13E-44F7-8F3C-00C8B30ACB7A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).